Somatic mutation profile of tumor specimen TARGET-10-PANSYA-09A (aliquot TARGET-10-PANSYA-09A-01D) from TARGET case TARGET-10-PANSYA, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.0 years (1,443 days).
Specimen TARGET-10-PANSYA-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 37f52902-937b-498b-ba01-a1ab2fa7f5b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANSYA-10A (Blood Derived Normal), aliquot TARGET-10-PANSYA-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4eb3af7-23ff-4561-bc1b-f6d7357fb88d

The open-access MAF lists 18 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Intron 3, Silent 3, 3'UTR 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRB3 | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.165); catalogued as rs750329964; called by muse, mutect2, varscan2
- BCORL1 | c.839C>T p.S280L | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV99501212; called by muse, mutect2, varscan2
- CDH11 | c.1063G>A p.D355N | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs747102834, COSV51774410, COSV51776848, COSV99219561; called by muse, mutect2
- FHOD3 | c.2185G>C p.E729Q (on ENST00000359247 / NM_001281739.3; = p.E746Q on NM_025135.5) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs773646639; called by muse, mutect2, varscan2
- ILDR1 | c.1477C>T p.R493W (on ENST00000344209 / NM_001199799.2; = p.R449W on NM_175924.4) | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as rs556882881, COSV56552149; called by muse, mutect2, varscan2
- NCAM1 | c.1189G>A p.A397T (on ENST00000316851 / NM_181351.5; = p.A387T on NM_000615.7) | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs781876684, COSV57518403; called by muse, mutect2, varscan2
- RAPGEF2 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs780273444; called by muse, mutect2, varscan2
- OR10A4 | c.303G>C p.Q101H | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TPR | c.5359G>C p.E1787Q | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- F8 | c.4512G>A p.L1504= | Silent (SNP) | VAF 39/80 reads (49%) | catalogued as CD073633; called by muse, mutect2, varscan2
- PLA2G4C | c.57C>T p.A19= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as rs749663476, COSV62787591; called by muse, mutect2, varscan2
- RNF148 | c.306G>T p.L102= | Silent (SNP) | VAF 47/90 reads (52%) | called by muse, mutect2, varscan2
- ARHGAP8 | c.80-181G>C | Intron (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
- C3P1 | n.3342G>A | RNA (SNP) | VAF 33/84 reads (39%) | catalogued as rs781172690; called by muse, mutect2, varscan2
- MCRIP1 | c.229+43C>G | Intron (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2, varscan2
- PPP4R3C | c.-36G>A | 5'UTR (SNP) | VAF 39/67 reads (58%) | called by muse, mutect2, varscan2
- SLC22A12 | c.*47C>T | 3'UTR (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- TTN | c.10360+3722T>A | Intron (SNP) | VAF 56/119 reads (47%) | catalogued as COSV60013841; called by muse, mutect2, varscan2
